Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8364, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8364-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted]	[Redacted]	Microscopic Description
[Redacted]		

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
		STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Fundus Tumor size: 8 x 6 x 1.7 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma, diffuse type Histologic grade: Tumor extent: Adjacent structures (specify) - Omentum Lymph nodes: 3/11 positive for metastasis (Intraabdominal 3/11) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file 9a347609-0084-45d9-bcfc-7905cfe8e666 (TCGA-BR-8364.02BBC59E-5550-4D09-BD79-36976EEEB62E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).